CCDI case PBCJJX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/322ad7c9-5889-400e-b9cf-9d75d62c5313

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 22.3 years (8,138 days).

Biospecimens (3 samples)
- Sample 0DTB89: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTB8M: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DTB92: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
